Surgical pathology report (de-identified scan), TCGA case TCGA-N9-A4PZ, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MD Anderson, specimen TCGA-N9-A4PZ-01A (Primary Tumor).

[page 1 of 2]
Specimen Date/Time:

DIAGNOSIS

- (A) UTERUS, CERVIX, PARAMETRIUM, BOTH TUBES, BOTH OVARIES:
MALIGNANT MIXED MULLERIAN TUMOR (CARCINOSARCOMA) ARISING IN AN ENDOMETRIAL POLYP INVADING 4.0 MM INTO AN 18.0 MM THICK MYOMETRIUM. (SEE COMMENT)
TUMOR INVADES 14.0 MM INTO A 15.0 MM THICK CERVICAL STROMA (ANTERIOR LIP) WITH TUMOR 5.0 MM FROM THE INKED ANTERIOR PARACERVICAL SOFT TISSUE MARGIN.
LYMPHOVASCULAR INVASION PRESENT.
METASTATIC CARCINOMA PRESENT IN ONE LEFT PARAMETRIAL LYMPH NODE (1/1).
Uterine leiomyomata.
Vaginal cuff and bilateral parametrial resection margins, no tumor present.
Surface adhesions, bilateral ovaries.
Right paratubal cyst.
Left fallopian tube, no pathologic change.
- (B) PORTION OF RIGHT PELVIC LYMPH NODE:
METASTATIC CARCINOMA IN LYMPHOID TISSUE.
- (C) RIGHT PARA-AORTIC LYMPH NODE:
One lymph node, no tumor present (0/1).
- (D) HIGH RIGHT PARA-AORTIC LYMPH NODE:
METASTATIC CARCINOMA PRESENT IN ONE OF TWO LYMPH NODES (1/2).
- (E) LEFT PELVIC LYMPH NODE:
One lymph node, no tumor present (0/1).

ICD-0-3
Mixed Mullerian Tumor 8550/3
Site: Path Endometrium C54.1
Cervix Uterus, NOS C55.9

Entire report and diagnosis complete

COMMENT

The malignant mixed Mullerian tumor is composed of 60% carcinomatous elements (endometrioid adenocarcinoma, FIGO grade 3, and uterine papillary serous carcinoma) and 40% sarcomatous elements (chondrosarcoma and unclassified sarcoma). The myoinvasive tumor and tumor involving the cervix is composed entirely of carcinoma.

GROSS DESCRIPTION

(A) UTERUS, CERVIX, PARAMETRIUM, BOTH TUBES, BOTH OVARIES - A uterus (15.0 x 9.0 x 6.5 cm) with cervix (5.0 x 5.0 x 3.0 cm), unremarkable vaginal cuff (2.0 cm in length), bilateral parametrial tissue (4.5 x 2.5 x 2.0 cm, right; 6.0 x 2.5 x 2.5 cm, left), bilateral fallopian tubes (8.0 x 2.5 cm, right; 8.5 x 0.5 cm, left), and bilateral, unremarkable ovaries (3.0 x 1.5 x 1.0 cm, right; 2.0 x 1.2 x 0.7 cm, left).
The endometrial cavity has a tan-yellow, partially necrotic and hemorrhagic polypoid mass (9.0 x 7.5 x 4.5 cm) attached to the anterior endometrium and fundus. There is no myometrial invasion grossly, and the myometrium ranges from 1.6 to 2.0 cm thick in the area underlying the tumor. The anterior cervix has a tan-white mass (5.0 x 3.0 x 1.2 cm) involving the ectocervix and endocervical canal, with possible extension into the lower uterine segment. Grossly, there is nearly full thickness cervical stromal invasion. The parametrial tissue is grossly uninvolved.

[page 2 of 2]
The posterior lower uterine segment has a cystic polyp (0.9 x 0.7 x 0.4 cm). The myometrium has two, white, well-circumscribed nodules (0.6 cm each). The bilateral fallopian tubes have multiple paratubal cysts.

Representative portions of endometrial mass and myometrium are submitted to tumor bank.

INK CODE: Black - soft tissue surface around the cervix.

SECTION CODE: A1-A10, entire right parametrium, (A1, A2, en face margin); A11-A25, entire left parametrium (A11, A12, en face margin); A26, en face vaginal cuff margin, 12 to 3 o'clock; A27, en face vaginal cuff margin, 3 to 6 o'clock; A28, en face vaginal cuff margin, 6 to 9 o'clock; A29, en face vaginal cuff margin, 9 to 12 o'clock; A30-A33, representative endometrial mass with full thickness myometrium; A34-A43, representative endometrial mass; A44, A45, myometrial nodules; A46-A49, anterior cervix with tumor (A46 and A47, one section divided; A48 and A49, one section divided); A50, additional anterior cervical tumor; A51-A54, anterior endocervix to lower uterine segment, consecutive sections from inferior to superior; A55, A56, posterior cervix, one section divided; A57-A60, posterior lower uterine segment with polyp entirely submitted; A61, representative posterior endomyometrium; A62, representative right fallopian tube; A63, representative right ovary; A64, representative left fallopian tube; A65, representative left ovary.

(B) PORTION OF RIGHT PELVIC LYMPH NODE - Two tan tissue fragments (4.0 x 3.0 x 2.0 cm; 0.9 x 0.7 x 0.5 cm) with metastatic tumor in the larger fragment.

SECTION CODE: B1-B3, representative large fragment; B4, small fragment.

(C) RIGHT PARA-AORTIC LYMPH NODE - A yellow tissue fragment (2.0 x 1.0 x 0.6 cm) with one lymph node (0.9 x 0.6 x 0.4 cm) entirely submitted in C.

(D) HIGH RIGHT PARA-AORTIC LYMPH NODE - Two tan tissue fragments (2.2 x 2.0 x 1.2 cm in aggregate) with the larger grossly involved by metastatic tumor.

SECTION CODE: D1 and D2, representative large fragment; D3, small fragment entirely submitted.

(E) LEFT PELVIC LYMPH NODE - One lymph node (1.2 x 0.6 x 0.4 cm) entirely submitted in E.

CLINICAL HISTORY

Endometrial cancer.

SNOMED CODES

T-83020, M-89503, T-C4600, T-C4400, M-89506

"Some tests reported here may have been developed and performance characteristics determined specifically cleared or approved by the U.S. Food and Drug Administration."

tests have not been

Released by:

-----END OF REPORT-----

Preliminary: 10/10/12 LW

Reviewed (initials):	UML	10/11/12

Source: NCI Genomic Data Commons file ee3a3b80-4d83-4870-b9ed-e98d18b7fe07 (TCGA-N9-A4PZ.BF339822-1A65-465B-BD96-DCCE41FCB2D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).